Somatic mutation profile of tumor specimen ALCH-B2SB-TTP1-A (aliquot ALCH-B2SB-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.1 years (28,170 days).
Specimen ALCH-B2SB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 348deff7-a3fb-4cb4-8ddf-953303f3c8c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SB-NB1-A (Blood Derived Normal), aliquot ALCH-B2SB-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ccb8b13-0736-4f28-a2d2-2ea3e88a59e1

The open-access MAF lists 371 somatic variants for this specimen: 247 protein-altering or splice-affecting, 66 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 219, Silent 66, Intron 31, Nonsense Mutation 12, Splice Site 11, RNA 10, 3'UTR 6, 5'UTR 5, 5'Flank 5, Frame Shift Del 4, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 88/421 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 152/635 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANTXRL | c.1766C>G p.S589C | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1354663767; called by muse, mutect2
- ARHGAP22 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs779934730; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 132/817 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59479257; called by muse, mutect2, varscan2
- BCAS2 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV65767475; called by muse, mutect2, varscan2
- CACNA2D1 | c.1516-2A>T p.X506_splice | Splice Site (SNP) | VAF 66/369 reads (18%) | catalogued as COSV100666996; called by muse, varscan2
- CDH9 | c.1349C>A p.S450* | Nonsense Mutation (SNP) | VAF 19/329 reads (6%) | catalogued as COSV50295740; called by muse, mutect2
- CDK5RAP2 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 58/561 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs751126483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELA2A | c.40+1G>A p.X14_splice | Splice Site (SNP) | VAF 50/278 reads (18%) | catalogued as rs1251009829; called by muse, mutect2, varscan2
- CFDP1 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52210489; called by muse, mutect2, varscan2
- CHRM2 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as rs759119090, COSV100280757; called by muse, mutect2
- COL4A6 | c.4915G>A p.A1639T | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760794179; called by muse, mutect2, varscan2
- CPXCR1 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 16/245 reads (7%) | catalogued as COSV52162331, COSV99342314; called by muse, mutect2
- CPXM2 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV104384647; called by muse, varscan2
- DENND1B | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294157670; called by muse, mutect2, varscan2
- DMRT3 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1207645608, COSV51904506; called by muse, mutect2, varscan2
- DNAH5 | c.3093G>T p.Q1031H | Missense Mutation (SNP) | VAF 275/962 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54220071, COSV99449346; called by muse, mutect2, varscan2
- EGF | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 67/687 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54485841, COSV99490313; called by muse, mutect2
- EIF3A | c.3482G>T p.G1161V | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs1454706308, COSV100974911; called by muse, varscan2
- ELFN1 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 161/625 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV70035343; called by muse, mutect2, varscan2
- EPHA5 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56653833; called by muse, mutect2
- FAM171A1 | c.2305G>T p.V769F | Missense Mutation (SNP) | VAF 125/336 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.201); catalogued as COSV65315873; called by muse, mutect2, varscan2
- GLCCI1 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 86/449 reads (19%) | catalogued as COSV99780732; called by muse, mutect2, varscan2
- GSX2 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 134/610 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58842939; called by muse, mutect2, varscan2
- HMGN2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs777724331; called by muse, mutect2
- HMGN2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as COSV63524790; called by muse, mutect2
- IGSF10 | c.4303A>G p.T1435A | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.339); catalogued as rs1314830828; called by muse, mutect2
- ITGA11 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs932298022; called by muse, mutect2, varscan2
- KCNS2 | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV99075376; called by muse, mutect2, varscan2
- KNG1 | c.424T>A p.C142S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889341254; called by muse, mutect2
- LRP1B | c.6683C>T p.A2228V | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs893660310; called by muse, mutect2, varscan2
- MAGEB6B | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 96/496 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV69689925; called by muse, mutect2, varscan2
- MAP3K4 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs766571378; called by muse, mutect2, varscan2
- MNDA | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100933440; called by muse, mutect2, varscan2
- NRXN1 | c.291C>G p.C97W | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV68017838; called by muse, mutect2, varscan2
- NYAP1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745503115; called by muse, mutect2, varscan2
- NYAP2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1039068937, COSV56006471, COSV99797136; called by muse, mutect2
- OR10T2 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 78/415 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs539828963, COSV57781131, COSV57782220; called by muse, mutect2, varscan2
- OR2C3 | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 163/792 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV63574605; called by muse, mutect2, varscan2
- OR2T3 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 104/1003 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs750699679, COSV62082340; called by muse, mutect2, varscan2
- OR4C13 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 37/388 reads (10%) | catalogued as rs782759084, COSV101634140, COSV73648626; called by muse, mutect2
- OR51A7 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63788905; called by muse, mutect2, varscan2
- OR51G1 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58971313; called by muse, mutect2, varscan2
- OR52B4 | c.864G>C p.M288I | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV68769616; called by muse, mutect2, varscan2
- OR5AN1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149354660; called by mutect2, varscan2
- OR5D13 | c.922G>T p.V308F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62334978; called by mutect2, varscan2
- PKHD1 | c.10265G>T p.W3422L | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1562044017; called by muse, mutect2, varscan2
- PLEKHO1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1553821517; called by muse, mutect2, varscan2
- PLPPR5 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as rs199656479; called by muse, mutect2, varscan2
- PLXNA4 | c.2047del p.H683Mfs*13 | Frame Shift Del (DEL) | VAF 123/716 reads (17%) | catalogued as COSV58126323; called by mutect2, pindel, varscan2
- PTPRT | c.3079C>A p.R1027S | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61993792; called by muse, mutect2, varscan2
- RD3 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 68/791 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV100879201; called by muse, mutect2
- RGS8 | c.314C>T p.A105V (on ENST00000367556 / NM_001369564.2; = p.A123V on NM_033345.3) | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276555; called by muse, mutect2, varscan2
- RIMS1 | c.4035T>A p.S1345R | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99325867; called by muse, mutect2, varscan2
- RNF146 | c.86C>T p.A29V (on ENST00000368314 / NM_001242850.2; = p.A28V on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1199920617; called by muse, mutect2, varscan2
- RNF152 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 116/616 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100455406, COSV57189176; called by muse, mutect2, varscan2
- RTL1 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as rs757393111, COSV66016373; called by muse, mutect2
- RTL3 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58185357; called by muse, mutect2, varscan2
- SAG | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV68590389; called by muse, mutect2, varscan2
- SAGE1 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs148375834; called by muse, mutect2
- SCN1A | c.1711A>T p.R571* | Nonsense Mutation (SNP) | VAF 36/274 reads (13%) | catalogued as rs1553544915, COSV57690664; called by muse, mutect2, varscan2
- SGSM1 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 52/551 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as COSV68514365; called by muse, mutect2
- SIRPG | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 82/660 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs777710856, COSV53810965; called by muse, mutect2, varscan2
- SLC1A5 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69467006; called by muse, mutect2
- SLC39A14 | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99249657; called by muse, mutect2, varscan2
- SLC6A4 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1249507811; called by muse, mutect2
- SPATA31D1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 65/620 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs1227859145; called by muse, mutect2, varscan2
- SPG11 | c.5199del p.K1733Nfs*105 | Frame Shift Del (DEL) | VAF 24/191 reads (13%) | catalogued as CD121235; called by mutect2, pindel, varscan2
- SPTA1 | c.7180C>A p.Q2394K | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs773923538; called by muse, mutect2
- TIMM50 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 109/497 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs768686885; called by muse, mutect2, varscan2
- TLE6 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as rs1272586283; called by muse, mutect2
- TRIML2 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 94/436 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV58715012; called by muse, mutect2, varscan2
- TSPO | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 49/642 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1244852377; called by muse, mutect2
- ZC3H11A | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 85/762 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV59749749; called by muse, mutect2, varscan2
- ZFHX4 | c.3171G>T p.K1057N | Missense Mutation (SNP) | VAF 55/604 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV51491512; called by muse, mutect2
- ZIC4 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 48/518 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs931730914; called by muse, mutect2
- ACAN | c.6970C>A p.P2324T | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS6 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRG4 | c.8162T>C p.L2721P | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH3A1 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMER3 | c.1448T>A p.F483Y | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AMOT | c.2043G>T p.W681C (on ENST00000371959 / NM_001113490.1; = p.W272C on NM_133265.3) | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKLE2 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKS3 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASXL3 | c.3130A>C p.S1044R | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ATRNL1 | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- B3GNT9 | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- B4GALNT3 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2
- BOD1L1 | c.4771G>T p.E1591* | Nonsense Mutation (SNP) | VAF 53/500 reads (11%) | called by muse, mutect2, varscan2
- BPNT1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- BRAF | c.839G>T p.C280F | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2CD5 | c.1522A>C p.I508L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CADM2 | c.792T>A p.D264E (on ENST00000407528 / NM_001167674.2; = p.D266E on NM_153184.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2
- CC2D1A | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCND2 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 78/677 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CD37 | c.771C>G p.L257= | Splice Region (SNP) | VAF 43/911 reads (5%) | called by muse, mutect2
- CDH11 | c.-298+1G>T | Splice Site (SNP) | VAF 127/1016 reads (13%) | called by muse, mutect2, varscan2
- CDH12 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.617); called by muse, mutect2
- CENPF | c.3917T>C p.I1306T | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP128 | c.30C>G p.H10Q | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CHD5 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CNGB3 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- COL20A1 | c.2176C>A p.R726S | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- COL22A1 | c.1168A>T p.I390F | Missense Mutation (SNP) | VAF 91/701 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CPB1 | c.528T>G p.H176Q | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPB1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPS1 | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 48/571 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CRYBG3 | c.2868G>T p.M956I | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2
- CSMD3 | c.10064C>A p.P3355Q (on ENST00000297405 / NM_001363185.1; = p.P3186Q on NM_052900.3) | Missense Mutation (SNP) | VAF 240/827 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1D | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 265/1321 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CTNND2 | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); called by muse, mutect2
- DENND1C | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- DHDH | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- DIP2B | c.1320T>A p.D440E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2
- DMXL1 | c.6185G>T p.W2062L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOCK2 | c.4972C>A p.P1658T | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DOCK2 | c.4973C>A p.P1658H | Missense Mutation (SNP) | VAF 27/329 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- EEF1A1 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- EFCAB12 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 75/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EFNB3 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPG5 | c.1509G>C p.L503F | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EPHA6 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- EPHA7 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EXO1 | c.26T>A p.F9Y | Missense Mutation (SNP) | VAF 189/669 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAAH | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 30/758 reads (4%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.936); called by muse, mutect2
- FAM222B | c.1322C>A p.P441Q | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM47B | c.1447T>A p.F483I | Missense Mutation (SNP) | VAF 92/524 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- FAM47C | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FANCA | c.2601+2T>G p.X867_splice | Splice Site (SNP) | VAF 52/516 reads (10%) | called by muse, mutect2
- FEZF1 | c.380T>A p.L127H | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- FLG | c.578T>C p.L193S | Missense Mutation (SNP) | VAF 73/572 reads (13%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FOXE1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 83/656 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FREM3 | c.2768T>A p.V923E | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- FSIP2 | c.11312C>A p.T3771N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT9 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 40/589 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- GPAM | c.895-2A>T p.X299_splice | Splice Site (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- GPR88 | c.1010C>G p.T337R | Missense Mutation (SNP) | VAF 34/674 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- GREB1 | c.3504G>T p.E1168D | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIK2 | c.2140C>G p.Q714E | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- HAAO | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 40/628 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HECW1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.13886C>A p.A4629D | Missense Mutation (SNP) | VAF 67/948 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.862); called by muse, mutect2
- HRNR | c.3286T>A p.S1096T | Missense Mutation (SNP) | VAF 303/2875 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IL5RA | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ISM2 | c.1017T>A p.S339R (on ENST00000342219 / NM_199296.3; = p.V224E on NM_182509.4) | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- JAK3 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- JPH3 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 157/695 reads (23%) | called by muse, mutect2, varscan2
- KCND2 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 110/635 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNJ16 | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 59/707 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDR | c.2684A>G p.H895R | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KERA | c.626C>A p.P209Q | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, varscan2
- KERA | c.587A>C p.Q196P | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KRTAP19-3 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 262/856 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LAMA3 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMB1 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- LIMK1 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2
- LMO7 | c.2608A>T p.T870S (on ENST00000357063; = p.T551S on NM_005358.5) | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- LOXL1 | c.1603-1G>C p.X535_splice | Splice Site (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- LPIN1 | c.1442-1G>T p.X481_splice | Splice Site (SNP) | VAF 150/723 reads (21%) | called by muse, mutect2, varscan2
- LRIG3 | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LRRIQ3 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, varscan2
- MEF2C | c.738A>T p.L246F | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MEGF10 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- MIPEP | c.2103G>T p.L701F | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MMP26 | c.5A>C p.Q2P | Missense Mutation (SNP) | VAF 47/468 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MRC2 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYH8 | c.5543G>T p.R1848L | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYL7 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.514); called by muse, mutect2
- NAA11 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NDUFV2 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NEK7 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NGEF | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRCAM | c.960C>A p.N320K (on ENST00000379028 / NM_001371124.1; = p.N314K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NXPH2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 74/464 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR13F1 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR1C1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- OR2G6 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- OR2M3 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 191/773 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2S2 | c.252C>G p.D84E | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- OR2T12 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 43/534 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR51G1 | c.83G>T p.W28L | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OR5K1 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR8B2 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OTOF | c.2650G>T p.A884S (on ENST00000272371 / NM_194248.3; = p.A137S on NM_004802.4) | Missense Mutation (SNP) | VAF 85/1048 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- PAQR9 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 100/1090 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PCDH12 | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 111/425 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCDHGA2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB2 | c.2175C>A p.D725E | Missense Mutation (SNP) | VAF 131/1190 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PDCD6IP | c.1768C>G p.Q590E | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PEX5 | c.1231G>T p.V411L (on ENST00000420616; = p.V403L on NM_000319.5) | Missense Mutation (SNP) | VAF 76/609 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PIK3R2 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 36/466 reads (8%) | called by muse, mutect2
- POMT2 | c.2085G>C p.W695C | Missense Mutation (SNP) | VAF 106/495 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU6F2 | c.1745T>C p.M582T | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PRMT7 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 55/638 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- PRR23A | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PRX | c.3328G>T p.G1110W | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- R3HCC1 | c.569G>C p.G190A (on ENST00000411463; = p.G150A on NM_001136108.3) | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPSN | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 119/884 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- REEP2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RFX4 | c.1032C>A p.F344L (on ENST00000392842 / NM_213594.3; = p.F250L on NM_032491.6) | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- RUFY4 | c.780G>T p.R260S | Missense Mutation (SNP) | VAF 113/549 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RXFP2 | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 87/557 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR2 | c.2552T>C p.L851P | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SAMD3 | c.359T>A p.I120N | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SCG2 | c.1837del p.A613Qfs*60 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel*
- SEMA5B | c.2208C>G p.S736R | Missense Mutation (SNP) | VAF 102/658 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SERAC1 | c.129-1G>C p.X43_splice | Splice Site (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- SERPINA11 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 62/826 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2
- SERPINA5 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- SH3GLB1 | c.1049G>C p.G350A | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC15A5 | c.658T>A p.W220R | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC22A8 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A13 | c.1337C>G p.T446R | Missense Mutation (SNP) | VAF 144/742 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A6 | c.448A>T p.T150S | Missense Mutation (SNP) | VAF 114/696 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOGA3 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 26/852 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SORBS2 | c.2129A>T p.K710I | Missense Mutation (SNP) | VAF 58/520 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.371); called by mutect2, varscan2
- SPAM1 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SPATA31A7 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 83/506 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPO11 | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2501A>G p.N834S (on ENST00000624873 / NM_001170637.4; = p.N835S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/777 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TECTA | c.5765C>A p.T1922K | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.836); called by muse, mutect2
- TFAP2D | c.1139+1G>T p.X380_splice | Splice Site (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- THOC2 | c.3058-2A>G p.X1020_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- TIGD4 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TIMM50 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 108/503 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TKFC | c.430A>T p.T144S | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TLN1 | c.6807G>T p.L2269F | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TLR4 | c.2439A>T p.K813N (on ENST00000355622 / NM_138554.5; = p.K773N on NM_003266.4) | Missense Mutation (SNP) | VAF 71/513 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TMEM117 | c.482G>T p.W161L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM132C | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 156/745 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM132C | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.39); called by muse, mutect2
- TMEM185A | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 115/1628 reads (7%) | called by muse, mutect2
- TNIP1 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TPK1 | c.686T>A p.V229E | Missense Mutation (SNP) | VAF 49/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPC1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.393); called by muse, mutect2
- TRPM4 | c.371del p.G124Dfs*154 | Frame Shift Del (DEL) | VAF 36/290 reads (12%) | called by pindel, varscan2
- TRPM7 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TTN | c.23957A>T p.K7986M (on ENST00000591111; = p.K7059M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | PolyPhen possibly damaging (0.852); called by muse, mutect2
- UTP4 | c.1072T>C p.W358R | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZCCHC7 | c.1132A>T p.I378F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZMYM4 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF275 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF423 | c.2555G>T p.G852V (on ENST00000563137 / NM_001379286.1; = p.G844V on NM_015069.4) | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ZNF598 | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF611 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF804B | c.1800C>A p.N600K | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA3 | c.639C>T p.A213= | Silent (SNP) | VAF 96/785 reads (12%) | catalogued as rs778504757, COSV100068242; called by muse, mutect2, varscan2
- ACCSL | c.855C>A p.V285= | Silent (SNP) | VAF 62/326 reads (19%) | called by muse, mutect2, varscan2
- ACSL4 | c.45C>A p.V15= | Silent (SNP) | VAF 43/145 reads (30%) | called by muse, mutect2, varscan2
- APOB | c.4521G>A p.R1507= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- ARHGAP21 | c.2094A>G p.E698= | Silent (SNP) | VAF 72/287 reads (25%) | called by muse, mutect2, varscan2
- ATN1 | c.1851C>T p.V617= | Silent (SNP) | VAF 36/348 reads (10%) | catalogued as COSV63111203; called by muse, mutect2
- ATP1A3 | c.1749G>T p.T583= (on ENST00000545399 / NM_001256214.2; = p.T570= on NM_152296.5) | Silent (SNP) | VAF 150/732 reads (20%) | catalogued as COSV57490306; called by muse, mutect2, varscan2
- ATRX | c.3687G>T p.V1229= | Silent (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- BCL9 | c.1630C>T p.L544= | Silent (SNP) | VAF 18/478 reads (4%) | catalogued as COSV52348219; called by muse, mutect2
- CCDC74B | c.477T>A p.T159= | Silent (SNP) | VAF 132/708 reads (19%) | called by muse, varscan2
- CD22 | c.1743G>T p.A581= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2
- CDHR5 | c.2403C>T p.N801= (on ENST00000358353 / NM_001171968.2; = p.N807= on NM_021924.5) | Silent (SNP) | VAF 78/762 reads (10%) | catalogued as rs147490212; called by muse, mutect2
- CILP2 | c.1950C>T p.P650= | Silent (SNP) | VAF 38/363 reads (10%) | catalogued as rs773678475; called by muse, mutect2, varscan2
- CKAP2L | c.1005A>G p.T335= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- COL7A1 | c.6174A>C p.G2058= | Silent (SNP) | VAF 41/247 reads (17%) | called by muse, mutect2, varscan2
- COL7A1 | c.676C>A p.R226= | Silent (SNP) | VAF 35/412 reads (8%) | catalogued as CM960403, COSV100095004; called by muse, mutect2
- CRACD | c.651C>A p.S217= | Silent (SNP) | VAF 30/922 reads (3%) | catalogued as COSV51721559, COSV51735396, COSV99950170; called by muse, mutect2
- DCN | c.807T>A p.P269= | Silent (SNP) | VAF 65/495 reads (13%) | called by muse, mutect2, varscan2
- DDX42 | c.2295C>A p.G765= | Silent (SNP) | VAF 63/306 reads (21%) | called by muse, mutect2, varscan2
- DISP2 | c.1914C>A p.P638= | Silent (SNP) | VAF 45/347 reads (13%) | catalogued as COSV51141102; called by muse, mutect2, varscan2
- DNAH5 | c.10713T>C p.P3571= | Silent (SNP) | VAF 47/683 reads (7%) | catalogued as rs769775818; called by muse, mutect2
- DOK7 | c.1260C>A p.P420= | Silent (SNP) | VAF 63/346 reads (18%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.1932T>A p.S644= | Silent (SNP) | VAF 62/336 reads (18%) | called by muse, varscan2
- F2R | c.1143C>T p.Y381= | Silent (SNP) | VAF 39/362 reads (11%) | catalogued as rs757455751; called by muse, mutect2, varscan2
- GLRA2 | c.277C>A p.R93= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV99491468; called by muse, mutect2
- HTR6 | c.1119C>A p.P373= | Silent (SNP) | VAF 219/885 reads (25%) | called by muse, mutect2, varscan2
- HUS1 | c.486C>G p.V162= | Silent (SNP) | VAF 21/239 reads (9%) | called by muse, mutect2
- IRF2BP2 | c.549G>T p.A183= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as COSV64015344; called by muse, mutect2
- ITGAX | c.393C>G p.P131= | Silent (SNP) | VAF 83/388 reads (21%) | called by muse, mutect2, varscan2
- ITIH6 | c.1348C>A p.R450= | Silent (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2, varscan2
- KCNJ1 | c.924C>T p.C308= | Silent (SNP) | VAF 46/486 reads (9%) | called by muse, mutect2
- KCNJ9 | c.666G>A p.P222= | Silent (SNP) | VAF 65/1137 reads (6%) | catalogued as COSV63631706; called by muse, mutect2
- KCNN3 | c.2130C>A p.A710= (on ENST00000618040 / NM_001204087.1; = p.A695= on NM_002249.6) | Silent (SNP) | VAF 96/555 reads (17%) | called by muse, varscan2
- KL | c.2649C>T p.D883= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs149545256; called by muse, mutect2, varscan2
- LAMA1 | c.132G>A p.K44= | Silent (SNP) | VAF 56/701 reads (8%) | called by muse, mutect2
- LOXHD1 | c.4389G>T p.S1463= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2
- MMP23B | c.129G>A p.P43= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs1242871556; called by muse, mutect2, varscan2
- MUC17 | c.5652C>A p.T1884= | Silent (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- NALCN | c.2931T>A p.P977= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- NELL2 | c.1455G>A p.E485= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs1425243257; called by muse, mutect2, varscan2
- NLRP3 | c.1926A>G p.Q642= | Silent (SNP) | VAF 77/604 reads (13%) | called by muse, mutect2, varscan2
- OCSTAMP | c.549G>T p.R183= | Silent (SNP) | VAF 58/356 reads (16%) | called by muse, mutect2, varscan2
- OR10H5 | c.405C>T p.L135= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as rs867071555; called by muse, mutect2
- OR1C1 | c.792C>G p.S264= | Silent (SNP) | VAF 37/346 reads (11%) | called by muse, mutect2, varscan2
- OR52A1 | c.444T>A p.T148= | Silent (SNP) | VAF 67/276 reads (24%) | called by muse, mutect2, varscan2
- OR5H14 | c.79C>T p.L27= | Silent (SNP) | VAF 26/301 reads (9%) | catalogued as rs757361927, COSV101454215, COSV71194398; called by muse, mutect2, varscan2
- OR8B3 | c.393G>T p.L131= | Silent (SNP) | VAF 36/577 reads (6%) | called by muse, mutect2
- PCDH18 | c.1996C>T p.L666= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1629G>A p.P543= | Silent (SNP) | VAF 137/1615 reads (8%) | catalogued as rs782688537, COSV65370471; called by muse, mutect2
- PCK1 | c.1422C>T p.I474= | Silent (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- PHRF1 | c.1446G>T p.G482= (on ENST00000264555 / NM_001286581.2; = p.G481= on NM_020901.4) | Silent (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- POM121L12 | c.438T>G p.R146= | Silent (SNP) | VAF 70/957 reads (7%) | called by muse, mutect2
- PRSS58 | c.696C>A p.P232= | Silent (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- REG3G | c.306C>T p.I102= | Silent (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- RELB | c.1056C>T p.D352= | Silent (SNP) | VAF 54/511 reads (11%) | catalogued as rs202054363; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.2553G>T p.L851= | Silent (SNP) | VAF 87/333 reads (26%) | called by muse, mutect2, varscan2
- SLC44A2 | c.720C>A p.V240= | Silent (SNP) | VAF 89/432 reads (21%) | catalogued as COSV59839334; called by muse, varscan2
- SLC6A3 | c.1389C>T p.C463= | Silent (SNP) | VAF 194/2031 reads (10%) | catalogued as rs768878455; called by muse, mutect2
- SNX14 | c.195C>T p.F65= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- TRAF7 | c.1470C>T p.N490= | Silent (SNP) | VAF 33/392 reads (8%) | catalogued as rs756602651; called by muse, mutect2
- TRERF1 | c.1998G>A p.P666= | Silent (SNP) | VAF 260/795 reads (33%) | catalogued as rs745493984; called by muse, mutect2, varscan2
- TUBA3C | c.957C>T p.Y319= | Silent (SNP) | VAF 125/523 reads (24%) | called by muse, mutect2, varscan2
- USP40 | c.2112C>A p.P704= | Silent (SNP) | VAF 45/386 reads (12%) | called by muse, mutect2, varscan2
- VWF | c.7878C>A p.P2626= | Silent (SNP) | VAF 71/769 reads (9%) | called by muse, mutect2
- XIRP1 | c.855C>A p.P285= | Silent (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- ZNF408 | c.1533G>A p.L511= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as COSV100305386; called by muse, mutect2
- AC006288.1 | n.220G>T | RNA (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- AC116351.1 | n.864C>A | RNA (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2
- ADRB2 | c.*27C>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100019237; called by mutect2, varscan2
- AL353804.7 | chrX:73846443 G>C | 5'Flank (SNP) | VAF 48/476 reads (10%) | called by muse, mutect2
- AMPH | c.1182+721G>A | Intron (SNP) | VAF 33/439 reads (8%) | called by muse, mutect2
- ANKMY2 | c.67+812T>G | Intron (SNP) | VAF 40/620 reads (6%) | called by muse, mutect2
- AP000769.3 | chr11:65503766 A>C | 5'Flank (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+36T>A | Intron (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- ATXN2 | c.731+984A>T | Intron (SNP) | VAF 42/467 reads (9%) | called by muse, mutect2
- C12orf54 | c.168+182T>C | Intron (SNP) | VAF 5/34 reads (15%) | catalogued as rs572738575; called by mutect2, varscan2
- C22orf34 | n.950G>A | RNA (SNP) | VAF 20/237 reads (8%) | catalogued as rs985300391; called by muse, mutect2
- C7orf65 | n.318C>G | RNA (SNP) | VAF 93/1011 reads (9%) | called by muse, mutect2
- CD1A | c.*6A>C | 3'UTR (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- CHN1 | c.-407G>T | 5'UTR (SNP) | VAF 47/293 reads (16%) | called by muse, mutect2, varscan2
- CORO1C | c.-5-1481G>T | Intron (SNP) | VAF 8/94 reads (9%) | catalogued as rs1002011833, COSV99776346; called by muse, mutect2
- CSH1 | c.456+48G>A | Intron (SNP) | VAF 179/844 reads (21%) | catalogued as rs780258409; called by muse, mutect2, varscan2
- DCDC1 | c.*29A>G | 3'UTR (SNP) | VAF 22/154 reads (14%) | catalogued as rs1227074399; called by muse, mutect2, varscan2
- DCK | c.757-638T>A | Intron (SNP) | VAF 49/176 reads (28%) | called by muse, mutect2, varscan2
- EIF3H | chr8:116755955 C>T | 5'Flank (SNP) | VAF 146/879 reads (17%) | called by muse, mutect2, varscan2
- EMD | c.-7A>C | 5'UTR (SNP) | VAF 72/718 reads (10%) | catalogued as rs797044612; ClinVar: uncertain significance; called by muse, mutect2
- EYS | c.1767-7191T>A | Intron (SNP) | VAF 14/96 reads (15%) | called by mutect2, varscan2
- FAM90A27P | n.638C>T | RNA (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- FECH | c.*30C>T | 3'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- FOLR3 | c.169-37G>T | Intron (SNP) | VAF 90/365 reads (25%) | called by muse, mutect2, varscan2
- GABRG3 | c.271-55186G>T | Intron (SNP) | VAF 45/286 reads (16%) | called by muse, mutect2, varscan2
- GLB1L3 | c.877-1961A>G | Intron (SNP) | VAF 32/318 reads (10%) | catalogued as rs763671951; called by muse, mutect2
- GPM6A | c.37+24831C>T | Intron (SNP) | VAF 69/355 reads (19%) | called by muse, mutect2, varscan2
- GREB1 | c.901+13G>T | Intron (SNP) | VAF 140/808 reads (17%) | called by muse, mutect2, varscan2
- HADH | c.133-4860G>A | Intron (SNP) | VAF 40/399 reads (10%) | catalogued as rs889957234; called by muse, mutect2, varscan2
- HLA-DQA1 | c.-21T>A | 5'UTR (SNP) | VAF 29/239 reads (12%) | called by muse, mutect2
- ITGA4 | c.556+592C>A | Intron (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- ITGAX | c.318+38G>T | Intron (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
- MAEA | c.579+1009C>T | Intron (SNP) | VAF 39/264 reads (15%) | catalogued as rs747320397; called by muse, mutect2, varscan2
- MGAM | c.4619-11306G>T | Intron (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- MPRIP | c.2163+4827G>A | Intron (SNP) | VAF 21/181 reads (12%) | catalogued as rs1239270660; called by muse, mutect2, varscan2
- MRPS36P1 | chr3:6770007 C>A | 3'Flank (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- NCF1C | n.719C>G | RNA (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- NEDD4L | c.1125+36G>A | Intron (SNP) | VAF 21/189 reads (11%) | called by muse, mutect2, varscan2
- NEDD4L | c.1125+37G>T | Intron (SNP) | VAF 22/196 reads (11%) | catalogued as rs1360376801; called by muse, mutect2
- PPFIA2 | c.1131+60C>T | Intron (SNP) | VAF 12/128 reads (9%) | catalogued as rs749537004, COSV61020941; called by muse, mutect2
- PREPL | c.2094+21C>T | Intron (SNP) | VAF 18/333 reads (5%) | called by muse, mutect2
- RNF135 | c.-23C>T | 5'UTR (SNP) | VAF 51/594 reads (9%) | catalogued as rs1290591579; called by muse, mutect2
- RNF217-AS1 | n.1663C>A | RNA (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895705 C>T | 5'Flank (SNP) | VAF 72/244 reads (30%) | catalogued as rs767874212; called by muse, mutect2
- SAMD13 | c.226-4734C>G | Intron (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- SOHLH1 | c.-50T>A | 5'UTR (SNP) | VAF 70/397 reads (18%) | called by muse, mutect2, varscan2
- SRL | c.62-2769G>T | Intron (SNP) | VAF 47/434 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.4736C>A | RNA (SNP) | VAF 64/215 reads (30%) | called by muse, mutect2, varscan2
- STXBP2 | c.326-17C>T | Intron (SNP) | VAF 209/643 reads (33%) | catalogued as rs1413699908; called by muse, mutect2, varscan2
- TENT4B | chr16:50152988 G>A | 5'Flank (SNP) | VAF 49/467 reads (10%) | called by muse, mutect2, varscan2
- TMEM260 | c.857+22C>G | Intron (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- TUBB7P | n.544C>A | RNA (SNP) | VAF 304/1253 reads (24%) | called by muse, varscan2
- UBA1 | c.1576-417_1576-416del | Intron (DEL) | VAF 32/211 reads (15%) | called by mutect2, pindel, varscan2
- UNC5A | c.722-596G>A | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs1412122571; called by muse, mutect2
- VAPB | c.*5904del | 3'UTR (DEL) | VAF 33/340 reads (10%) | called by mutect2, pindel, varscan2
- XIRP2 | c.*1273G>T | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- ZEB1 | c.58+44446T>G | Intron (SNP) | VAF 95/276 reads (34%) | called by muse, mutect2, varscan2
- ZNF971P | n.1102C>T | RNA (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
